CCDI case PBCMDX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f58415e6-27e6-4fe9-ac9e-6b96de775f33

Demographics
Sex at birth: female.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.5 years (549 days).

Biospecimens (3 samples)
- Sample 0DW72J: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW72R: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DW72X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
